Somatic mutation profile of tumor specimen 0DNCOM from CCDI case PBCBIS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.5 years (4,576 days).
Specimen 0DNCOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22eb0563-21fb-4dc5-9286-03635ed59da5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCH3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6e5a8b5-6ddd-415c-b201-bfd2c600fb0d

The open-access MAF lists 20 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 2, 5'UTR 2, 3'UTR 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC126283.2 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 288/1201 reads (24%) | catalogued as rs121964913, CM041379, COSV67100279; ClinVar: risk factor; called by muse, varscan2
- CLNK | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 344/803 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57012508, COSV57015657; called by muse, varscan2
- KMT2C | c.596del p.R199Hfs*7 | Frame Shift Del (DEL) | VAF 372/1122 reads (33%) | catalogued as COSV51499603, COSV51504295; called by pindel, varscan2
- LIPC | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 190/1032 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs549763129; called by muse, varscan2
- NHLH1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 214/448 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1431620541, COSV57483728; called by muse, varscan2
- RPAP1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 88/462 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs367690635; called by muse, varscan2
- ANK2 | c.8855C>A p.T2952K | Missense Mutation (SNP) | VAF 414/1549 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.085); called by muse, varscan2
- CCAR2 | c.2049G>T p.M683I | Missense Mutation (SNP) | VAF 154/678 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, varscan2
- MIB1 | c.2422A>T p.M808L | Missense Mutation (SNP) | VAF 333/876 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- TMEM163 | c.821A>C p.D274A | Missense Mutation (SNP) | VAF 188/986 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CACNA1F | c.5751C>T p.F1917= | Silent (SNP) | VAF 162/818 reads (20%) | catalogued as rs1352913123, COSV59903205; called by muse, varscan2
- KLF7 | c.393C>T p.N131= | Silent (SNP) | VAF 83/774 reads (11%) | catalogued as rs200699335, COSV58742672; called by muse, varscan2
- TMEM132B | c.837C>T p.D279= | Silent (SNP) | VAF 134/664 reads (20%) | catalogued as rs370452958; called by muse, varscan2
- ZFP69 | c.1494C>T p.N498= | Silent (SNP) | VAF 546/1279 reads (43%) | catalogued as rs748836603, COSV65529536; called by muse, varscan2
- B3GLCT | c.-30C>A | 5'UTR (SNP) | VAF 62/174 reads (36%) | called by muse, varscan2
- NUP98 | c.2198-73T>C | Intron (SNP) | VAF 122/514 reads (24%) | called by muse, varscan2
- OGT | c.*67A>G | 3'UTR (SNP) | VAF 120/262 reads (46%) | called by muse, varscan2
- PCYT1B | c.*90G>T | 3'UTR (SNP) | VAF 102/450 reads (23%) | called by muse, varscan2
- TBX21 | c.-17_-14dup | 5'UTR (INS) | VAF 36/138 reads (26%) | called by pindel, varscan2
- UNC45A | c.2421+31C>T | Intron (SNP) | VAF 88/390 reads (23%) | catalogued as rs563467217, COSV67793623; called by muse, varscan2
